Somatic mutation profile of tumor specimen 0DT69G from CCDI case PBCJIE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 17.4 years (6,357 days).
Specimen 0DT69G: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cc6cd93-4f61-40b1-96f6-10e62fb8e4ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT69C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91f9df89-4238-43f3-b26f-0ad00d21a4f5

The open-access MAF lists 55 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 6, 3'UTR 2, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFP | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs376466369; called by muse, mutect2
- ASCL4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as rs778208723, COSV60816844; called by muse, mutect2, varscan2
- BAMBI | c.364+7G>A | Splice Region (SNP) | VAF 45/287 reads (16%) | catalogued as rs752721030; called by muse, mutect2, varscan2
- BRINP3 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 98/673 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755315472; called by muse, mutect2, varscan2
- BSN | c.11320C>T p.R3774C | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as rs752931204; called by muse, mutect2
- CRACD | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 87/509 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1403169865; called by muse, mutect2, varscan2
- CYP4F11 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.123); catalogued as rs1169183019, COSV56126449; called by muse, mutect2
- EVPL | c.4726C>T p.R1576W | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs750859177; called by muse, mutect2, varscan2
- MTDH | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs376219381; called by muse, mutect2
- MUC5B | c.4066G>A p.G1356R | Missense Mutation (SNP) | VAF 72/468 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773370059; called by muse, mutect2, varscan2
- MXRA5 | c.5231G>A p.G1744E | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV54227152; called by muse, mutect2, varscan2
- PCDH18 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs770250677, COSV61266724; called by muse, mutect2, varscan2
- PCDH7 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.069); catalogued as COSV62338756; called by muse, mutect2, varscan2
- PCSK4 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs756063239, COSV56298347; called by muse, mutect2, varscan2
- SNTG2 | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 36/745 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs886427448; called by muse, mutect2
- SYNRG | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 24/513 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs1376581348; called by muse, mutect2
- ZNF281 | c.2047A>G p.S683G | Missense Mutation (SNP) | VAF 154/926 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760762849, COSV54165622; called by muse, varscan2
- ADAMTS20 | c.5595G>T p.K1865N | Missense Mutation (SNP) | VAF 18/483 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- APOB | c.2121G>T p.K707N | Missense Mutation (SNP) | VAF 36/734 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLK4 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 43/660 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- DAB1 | c.920C>A p.S307Y (on ENST00000371231; = p.S274Y on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/695 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- HERC2 | c.4546C>T p.L1516F | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- KIF11 | c.2902A>T p.N968Y | Missense Mutation (SNP) | VAF 60/551 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- KIF26B | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MUC3A | c.4938G>C p.E1646D | Missense Mutation (SNP) | VAF 125/915 reads (14%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- NFKB2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 81/752 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- NPHP1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 52/749 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2
- PCDH17 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RIPK1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 54/614 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SPIB | c.604_606del p.S202del | In Frame Del (DEL) | VAF 39/295 reads (13%) | called by pindel, varscan2
- USP17L2 | c.1002T>A p.H334Q | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UTRN | c.1550C>A p.T517N | Missense Mutation (SNP) | VAF 62/691 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- WDR59 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 54/610 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); called by muse, mutect2
- BARX2 | c.213G>A p.P71= | Silent (SNP) | VAF 90/639 reads (14%) | catalogued as rs766390092; called by muse, mutect2, varscan2
- CBR3 | c.63C>T p.I21= | Silent (SNP) | VAF 60/551 reads (11%) | catalogued as rs1253922034; called by muse, mutect2, varscan2
- CYB561D2 | c.606C>T p.T202= | Silent (SNP) | VAF 63/557 reads (11%) | catalogued as COSV51702229; called by muse, mutect2, varscan2
- DYNC1H1 | c.9615C>T p.L3205= | Silent (SNP) | VAF 68/674 reads (10%) | catalogued as rs1209904325, COSV64139736; called by muse, mutect2, varscan2
- GREB1 | c.2817G>A p.P939= | Silent (SNP) | VAF 29/337 reads (9%) | catalogued as rs766981444, COSV52180385; called by muse, mutect2
- ITGAX | c.1419C>T p.T473= | Silent (SNP) | VAF 80/571 reads (14%) | catalogued as rs998010127; called by muse, mutect2, varscan2
- LRP6 | c.774G>A p.L258= | Silent (SNP) | VAF 46/938 reads (5%) | catalogued as COSV53793339; called by muse, mutect2
- MYH9 | c.1806G>A p.Q602= | Silent (SNP) | VAF 63/607 reads (10%) | catalogued as COSV99339957; called by muse, mutect2, varscan2
- PPP3R2 | c.168G>A p.R56= | Silent (SNP) | VAF 38/636 reads (6%) | called by muse, mutect2
- RNF126 | c.708C>T p.Y236= | Silent (SNP) | VAF 71/527 reads (13%) | catalogued as rs778420599; called by muse, mutect2
- SCYL2 | c.2055A>G p.K685= | Silent (SNP) | VAF 105/562 reads (19%) | called by muse, mutect2, varscan2
- SLC6A19 | c.462G>T p.P154= | Silent (SNP) | VAF 37/458 reads (8%) | catalogued as rs775341644; called by muse, mutect2
- TMEM121B | c.1635G>A p.P545= | Silent (SNP) | VAF 45/305 reads (15%) | catalogued as COSV58898097; called by muse, mutect2
- BOP1 | c.-1C>G | 5'UTR (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- BTN3A2 | c.*6+88A>C | Intron (SNP) | VAF 15/191 reads (8%) | called by muse, mutect2
- CAPN9 | c.1987+14G>A | Intron (SNP) | VAF 30/246 reads (12%) | catalogued as rs200722745, COSV55233954; called by muse, mutect2, varscan2
- CATSPER4 | c.*84C>T | 3'UTR (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2
- CD63 | c.256-55C>T | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs531047095; called by muse, mutect2, varscan2
- FCN3 | c.233-19C>T | Intron (SNP) | VAF 18/281 reads (6%) | catalogued as rs1054286585; called by muse, mutect2
- GNAI2 | c.*19G>A | 3'UTR (SNP) | VAF 50/323 reads (15%) | catalogued as rs782536669; called by muse, mutect2, varscan2
- POLR3C | c.1323+60C>G | Intron (SNP) | VAF 74/340 reads (22%) | called by muse, mutect2, varscan2
- VPS45 | c.1371+51G>A | Intron (SNP) | VAF 32/222 reads (14%) | called by muse, mutect2, varscan2
